MMRF case MMRF_2331 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dfec409b-10fc-43e3-9ca8-edb95d5419c7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.9 years (25,892 days); ISS stage: II; Days to last known disease status: 767 days (2.1 years); Days to last follow up: 767 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 767.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 1): M Protein 4.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.408 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.24 mg/dL; Immunoglobulin G 68.6 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.27 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 10.3 g/dL; Glucose 4.24 mmol/L.
- Day 64 (ECOG 1): M Protein 0.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.25 mg/dL; Immunoglobulin G 2.85 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 5.06 mmol/L.
- Day 177 (ECOG 1): M Protein 0.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.26 mg/dL; Immunoglobulin G 5.08 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 7.37 mmol/L.
- Day 204 (ECOG 1): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.26 mg/dL; Immunoglobulin G 5.04 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 303 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.057 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 4.72 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 227 ×10⁹/L.
- Day 410 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 4.72 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.12 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 4.07 mmol/L.
- Day 501 (ECOG 1): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 3.78 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 592 (ECOG 1): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 3.85 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.56 mmol/L.
- Day 676 (ECOG 1): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 4.59 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 4.13 mmol/L.

Other clinical attributes
- Day -23: Weight: 46 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_2331_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_2331_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
